Somatic mutation profile of tumor specimen TCGA-DV-5565-01A (aliquot TCGA-DV-5565-01A-01D-1534-10) from TCGA case TCGA-DV-5565, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.3 years (21,642 days).
Specimen TCGA-DV-5565-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d1c5b79-0167-4190-bf58-0cba58692c63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-5565-10A (Blood Derived Normal), aliquot TCGA-DV-5565-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4aa2d603-a649-402a-b7e9-635654ead0bf

The open-access MAF lists 60 somatic variants for this specimen: 51 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 8, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 1, In Frame Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC37A4 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193302882, CM980791, COSV58155100, COSV58155165; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABHD15 | c.1327G>T p.G443* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV56194905; called by muse, mutect2, varscan2
- ADGRE2 | c.2375G>T p.W792L | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs761872578, COSV59692009; called by muse, mutect2, varscan2
- AFF1 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57117526; called by muse, mutect2, varscan2
- AKAP9 | c.9562C>A p.L3188M (on ENST00000359028; = p.L3164M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/360 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as COSV62340203; called by muse, mutect2, varscan2
- ANKRD17 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 109/305 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV58216312; called by muse, mutect2, varscan2
- ATP2C2 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765718239, COSV52293308; called by muse, mutect2, varscan2
- CCDC15 | c.2788A>T p.N930Y | Missense Mutation (SNP) | VAF 125/378 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV61080536, COSV61083540; called by muse, mutect2, varscan2
- CCDC171 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs780250149, COSV52634946; called by muse, mutect2, varscan2
- CDHR5 | c.1348C>G p.Q450E | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.546); catalogued as rs750794067, COSV57641704; called by muse, mutect2, varscan2
- CLTCL1 | c.4528A>T p.I1510F | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV54226118; called by muse, mutect2, varscan2
- COL27A1 | c.1712T>A p.L571Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV61922337; called by muse, mutect2, varscan2
- COLGALT2 | c.1103T>G p.I368S | Missense Mutation (SNP) | VAF 103/305 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100730469; called by muse, mutect2, varscan2
- CSMD1 | c.10301G>A p.W3434* (on ENST00000520002; = p.W3433* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 203/374 reads (54%) | catalogued as COSV100144958; called by muse, varscan2
- DPYS | c.1022A>G p.D341G | Missense Mutation (SNP) | VAF 99/296 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1242547917, COSV60906864; called by muse, mutect2, varscan2
- ENY2 | c.253A>C p.K85Q | Missense Mutation (SNP) | VAF 275/850 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV60565371; called by muse, mutect2, varscan2
- EPG5 | c.6935C>A p.A2312D | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV56345628; called by muse, mutect2, varscan2
- FBN2 | c.7355A>C p.E2452A | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52496595; called by muse, mutect2, varscan2
- FOXRED2 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs762876668, COSV53399052; called by muse, mutect2, varscan2
- IL36B | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV52084707, COSV52089735; called by muse, mutect2, varscan2
- KATNAL1 | c.1014A>G p.G338= | Splice Region (SNP) | VAF 86/224 reads (38%) | catalogued as COSV101016762; called by muse, varscan2
- KIF3B | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65226954; called by muse, mutect2, varscan2
- LEP | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.054); catalogued as COSV58240718; called by muse, mutect2, varscan2
- LRP1 | c.8708A>G p.K2903R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99674884; called by muse, mutect2, varscan2
- MIER1 | c.1007A>G p.Y336C (on ENST00000355356 / NM_001077701.3; = p.Y353C on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 162/466 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62529336; called by muse, mutect2, varscan2
- MYBL2 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as rs1401780545, COSV53827885; called by muse, mutect2, varscan2
- MYT1 | c.1018T>A p.Y340N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV100114719, COSV60501797; called by muse, mutect2, varscan2
- NARS2 | c.378C>A p.F126L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55249961; called by muse, mutect2, varscan2
- NEK3 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 224/827 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99317489; called by muse, mutect2, varscan2
- OR1G1 | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV61029728, COSV61030128; called by muse, mutect2
- OR1M1 | c.14A>T p.N5I | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70036526; called by muse, mutect2, varscan2
- PABPC3 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV55798107; called by muse, mutect2, varscan2
- PAK6 | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756797198, COSV53044580; called by muse, mutect2, varscan2
- PDCL | c.212A>C p.Q71P | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750399527, COSV52342154; called by muse, mutect2
- PLB1 | c.3736G>A p.A1246T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.078); catalogued as COSV59820413; called by muse, mutect2, varscan2
- PRUNE2 | c.3074C>G p.S1025* | Nonsense Mutation (SNP) | VAF 138/361 reads (38%) | catalogued as COSV65038480; called by muse, mutect2, varscan2
- QSER1 | c.346G>C p.E116Q (on ENST00000399302; = p.E245Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 100/303 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV67899713; called by muse, mutect2, varscan2
- RAD51AP2 | c.1924A>T p.N642Y | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV67587460; called by muse, mutect2, varscan2
- RTTN | c.6269A>T p.D2090V | Missense Mutation (SNP) | VAF 179/511 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55342027; called by muse, mutect2, varscan2
- SIPA1L3 | c.2330G>C p.G777A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55909789; called by muse, mutect2, varscan2
- SNX29 | c.1195T>C p.S399P | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV60052598; called by muse, mutect2, varscan2
- SRRT | c.1610T>G p.L537R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99573840; called by muse, mutect2
- ST7 | c.1281C>G p.I427M (on ENST00000265437 / NM_021908.3; = p.I404M on NM_018412.4) | Missense Mutation (SNP) | VAF 208/412 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55380942; called by muse, mutect2, varscan2
- STX1A | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV56108721; called by muse, mutect2, varscan2
- TMEM266 | c.1232G>A p.C411Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs937888304; called by muse, varscan2
- TTN | c.92-1G>A p.X31_splice | Splice Site (SNP) | VAF 28/86 reads (33%) | catalogued as COSV59915561; called by muse, mutect2
- H2BC9 | c.16_24del p.K6_A8del | In Frame Del (DEL) | VAF 22/82 reads (27%) | called by mutect2, pindel, varscan2
- KDM5B | c.2684del p.D895Vfs*26 | Frame Shift Del (DEL) | VAF 44/147 reads (30%) | called by mutect2, pindel, varscan2
- LAMC1 | c.2745del p.C916Vfs*123 | Frame Shift Del (DEL) | VAF 58/179 reads (32%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UBASH3A | c.1868del p.C623Sfs*15 | Frame Shift Del (DEL) | VAF 57/192 reads (30%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.1428G>A p.L476= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV50819983, COSV50832774; called by muse, mutect2, varscan2
- FZD10 | c.813C>T p.C271= | Silent (SNP) | VAF 3/52 reads (6%) | catalogued as COSV57475876, COSV99969623; called by muse, mutect2
- IFNA6 | c.231C>A p.I77= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV66506235; called by muse, mutect2, varscan2
- IL10 | c.312C>T p.D104= | Silent (SNP) | VAF 61/200 reads (31%) | catalogued as COSV65594385; called by muse, mutect2, varscan2
- PLCG1 | c.3324G>A p.V1108= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as COSV54815939; called by muse, mutect2, varscan2
- RLF | c.4641A>G p.T1547= | Silent (SNP) | VAF 70/180 reads (39%) | catalogued as rs1044739, COSV65650871; called by muse, mutect2
- TDRP | c.195A>G p.K65= | Silent (SNP) | VAF 214/402 reads (53%) | catalogued as rs1270605742, COSV60704840; called by muse, mutect2, varscan2
- ZNF302 | c.945G>A p.K315= (on ENST00000627982; = p.K236= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV71063275; called by muse, mutect2, varscan2
- RPL23 | c.97+114G>T | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99834658; called by muse, mutect2, varscan2
